Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-A65F, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-A65F-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: LYMPH NODES, RIGHT PELVIC, SELECTIVE DISSECTION -
TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

PART 2: LYMPH NODES, LEFT PELVIC, SELECTIVE DISSECTION -
TWO LYMPH NODES, NEGATIVE FOR CARCINOMA (0/2).

PART 3: TISSUE ANTERIOR TO URETHRA, BIOPSY -
FIBROCONNECTIVE TISSUE, NEGATIVE FOR CARCINOMA.

PART 4: NEUROVASCULAR BUNDLE, LEFT, EXCISION -
NEGATIVE FOR CARCINOMA.

PART 5: PROSTATE, BILATERAL SEMINAL VESICLES AND DISTAL VASA DEFERENTIA, RADICAL PROSTATECTOMY -
A. INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA, ACINAR AND CRIBRIFORM TYPES, GLEASON
SCORE 4 + 5 = 9 (see comment).
B. CARCINOMA INVOLVES BOTH RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 3 cm.
C. CARCINOMA INVOLVES APPROXIMATELY 50% OF THE EXAMINED PROSTATE VOLUME.
D. CARCINOMA SHOWS MULTIFOCAL EXTRACAPSULAR EXTENSION.
E. EXTRACAPSULAR EXTENSION IS SEEN IN THE REGION OF THE RIGHT SEMINAL VESICLE (slide 5A), LEFT
SEMINAL VESICLE (slide 5C), ANTERIOR RIGHT BASE (slide 5Q) AND POSTERIOR LEFT BASE (slide 5AA).
F. CARCINOMA INVOLVES BILATERAL SEMINAL VESICLES.
G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
H. EXTENSIVE PERINEURAL INVASION IS IDENTIFIED.
I. ANGIOLYMPHATIC INVASION IS IDENTIFIED (slide 5C).
J. PATHOLOGIC TNM STAGE (AJCC 7th EDITION): pT3b N0 MX.
K. TNM HISTOLOGIC GRADE = G3-4.

COMMENT:

While the vast majority (over 99%) of this prostate adenocarcinoma shows Gleason pattern 4 and 5 components, a rare focus of Gleason pattern 3 adenocarcinoma is identified (slide 5F).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA: PSA value: 25
INVASIVE CA IDENTIFIED?: Yes
TUMOR HISTOLOGY: Adenocarcinoma NOS
PRIMARY GLEASON GRADE: 4
SECONDARY GLEASON GRADE: 5
GLEASON SUM SCORE: 9
GLEASON 4/5 PERCENTAGE: 99%
WEIGHT OF PROSTATE: 50.27gm
TUMOR SIZE: Maximum dimension: 3 cm
LOBE LATERALITY: Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR: > 25%
MULTIFOCAL DISEASE: Yes
HIGH GRADE PIN: No
EXTRAPROSTATIC EXTENSION: Yes - Multifocal
PERINEURAL INVASION: Yes
ANGIOLYMPHATIC INVASION: Yes
SEMINAL VESICLE INVASION: Yes
SURGICAL MARGIN INVOLVEMENT: All surgical margins free of tumor
RESIDUAL TUMOR: R0
LYMPH NODES EXAMINED: 4
LYMPH NODES POSITIVE: 0
T STAGE, PATHOLOGIC: pT3b
N STAGE, PATHOLOGIC: pN0
M STAGE, PATHOLOGIC: pMX
HISTOLOGIC GRADE: G3-4, Poorly differentiated/undifferentiated

ICDO-3

Adenocarcinoma w/mixed
subtypes 8255/3

Site: Prostate NOS
C61.9

JA 5/16/13

PATIENT HISTORY:

The patient is a year-old white male with a history of PSA value of 25. The patient also has a history of biopsy on [REDACTED], this biopsy reveals: poorly differentiated prostatic adenocarcinoma Gleason score 4+3=7 in the right and left lobes as well as Gleason score 4+4=8 in the transition zone.

PRE-OP DIAGNOSIS: prostate cancer

POST-OP DIAGNOSIS: same

PROCEDURE: radical prostatectomy.

Source: NCI Genomic Data Commons file 7f1e41a0-6576-4b35-a1de-eb02e558b430 (TCGA-EJ-A65F.635A6F68-B3A7-4856-BE21-C2DC0AADAA59.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).